Somatic mutation profile of tumor specimen TCGA-D8-A1XW-01A (aliquot TCGA-D8-A1XW-01A-11D-A14K-09) from TCGA case TCGA-D8-A1XW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.3 years (19,478 days).
Specimen TCGA-D8-A1XW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3f7a77c-d1b9-414e-931d-42706e48334a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XW-10A (Blood Derived Normal), aliquot TCGA-D8-A1XW-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a306b11b-f0b3-4e1d-99aa-54ffc1e9fec8

The open-access MAF lists 100 somatic variants for this specimen: 77 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 21, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 3, Translation Start Site 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376T>A p.Y126N | Missense Mutation (SNP) | VAF 31/50 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039483, CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRG6 | c.2254A>G p.T752A | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV51589291; called by muse, mutect2, varscan2
- ADGRL3 | c.1604C>G p.T535S (on ENST00000506720 / NM_001322402.2; = p.T467S on NM_015236.6) | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as COSV101547031, COSV101547234; called by muse, mutect2
- AFDN | c.3079-1G>C p.X1027_splice | Splice Site (SNP) | VAF 116/176 reads (66%) | catalogued as COSV100653132; called by muse, mutect2, varscan2
- ARFGEF1 | c.3765G>A p.M1255I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51605573; called by muse, mutect2, varscan2
- ASL | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV59188221; called by muse, mutect2, varscan2
- ATP2B2 | c.2547C>A p.S849R (on ENST00000352432; = p.S815R on NM_001683.5) | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59492805; called by muse, mutect2, varscan2
- ATP2B2 | c.2546G>C p.S849T (on ENST00000352432; = p.S815T on NM_001683.5) | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59492829; called by muse, mutect2, varscan2
- BBS10 | c.745C>A p.R249S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53880325; called by muse, mutect2, varscan2
- BLMH | c.507T>G p.Y169* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | catalogued as COSV55584879; called by muse, mutect2, varscan2
- BPIFC | c.532G>T p.V178F | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV100301112, COSV55911851; called by muse, mutect2, varscan2
- CASP8 | c.677A>T p.Y226F (on ENST00000432109 / NM_033355.3; = p.Y243F on NM_001228.4) | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51846313, COSV51848401; called by muse, mutect2, varscan2
- CCDC74B | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV60101413; called by muse, mutect2, varscan2
- CDC42BPB | c.5025A>C p.K1675N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.652); catalogued as COSV54486405; called by muse, mutect2, varscan2
- CECR2 | c.3964C>A p.H1322N (on ENST00000342247 / NM_001290047.2; = p.H1138N on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52838744; called by muse, mutect2, varscan2
- CFAP58 | c.1866T>A p.D622E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV63833491, COSV63834193; called by muse, mutect2, varscan2
- CPT1A | c.693C>A p.Y231* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV55754285; called by muse, mutect2, varscan2
- DIAPH1 | c.2218C>G p.P740A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV53880497; called by muse, mutect2, varscan2
- DNASE1L1 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV50010105; called by muse, mutect2, varscan2
- FAM83F | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV60999825; called by muse, mutect2, varscan2
- FHOD3 | c.3724T>C p.F1242L (on ENST00000359247 / NM_001281739.3; = p.F1259L on NM_025135.5) | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV99941565; called by muse, mutect2
- FMNL1 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58956035; called by muse, mutect2, varscan2
- FSTL5 | c.2348A>G p.K783R | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV60187512; called by muse, mutect2, varscan2
- GPR158 | c.469T>C p.Y157H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332241184, COSV100893787; called by muse, mutect2
- GRID1 | c.217T>A p.F73I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60021397; called by muse, mutect2, varscan2
- H3C11 | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV58899570; called by muse, mutect2, varscan2
- HMCN1 | c.7981G>C p.V2661L | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV54904108, COSV99630840; called by muse, mutect2
- IGSF1 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs780617557, COSV63836805; called by muse, mutect2, varscan2
- IL1R1 | c.1135G>C p.A379P | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99292678; called by muse, mutect2
- IL1RAP | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 38/122 reads (31%) | catalogued as COSV50760035; called by muse, mutect2, varscan2
- IMMT | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 85/338 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54486147; called by muse, mutect2, varscan2
- ITPKC | c.1255+2T>G p.X419_splice | Splice Site (SNP) | VAF 16/85 reads (19%) | catalogued as COSV54573965; called by muse, mutect2, varscan2
- KCNT2 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 104/484 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs190445712, COSV54091773; called by muse, mutect2, varscan2
- LCOR | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as COSV53715116; called by muse, mutect2, varscan2
- LCOR | c.2761A>G p.K921E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.547); catalogued as COSV53715124; called by muse, mutect2, varscan2
- LILRB1 | c.226A>T p.T76S (on ENST00000427581; = p.T40S on NM_006669.6) | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100207412; called by muse, mutect2
- LNX2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100310756; called by muse, mutect2
- LTN1 | c.2586T>G p.H862Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV63733384; called by muse, mutect2, varscan2
- MACROD2 | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 18/542 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99435624; called by muse, mutect2
- MYO1A | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs749042781, COSV55652797; called by muse, mutect2, varscan2
- NUAK1 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs757219955, COSV54601921; called by muse, mutect2, varscan2
- OR1A2 | c.310A>T p.M104L | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs761797215, COSV67936269; called by muse, mutect2, varscan2
- OR2T1 | c.601T>A p.C201S | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63541578; called by muse, mutect2, varscan2
- OR2T29 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs760400090, COSV60771320; called by muse, varscan2
- OR8D1 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV63441935, COSV63443029; called by muse, mutect2, varscan2
- PACSIN2 | c.249G>C p.W83C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54317812; called by muse, mutect2, varscan2
- PADI1 | c.227T>A p.M76K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV64938138; called by muse, mutect2, varscan2
- PAH | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.502); catalogued as rs199475678, CM045074, COSV61015245; ClinVar: not provided; called by muse, mutect2, varscan2
- PCDHB16 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782137635, COSV53360115; called by muse, mutect2, varscan2
- PSMA2 | c.474G>C p.W158C | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99785787; called by muse, mutect2
- PTPRJ | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV69250964; called by mutect2, varscan2
- RAB11FIP1 | c.3656C>G p.A1219G (on ENST00000330843 / NM_001002814.3; = p.A585G on NM_025151.5) | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV54759130; called by muse, mutect2, varscan2
- RSPH6A | c.1994T>G p.I665S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV54288412; called by muse, varscan2
- SDK1 | c.6299A>G p.D2100G | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67362321; called by muse, varscan2
- SH3BP4 | c.1442C>G p.P481R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60643260; called by muse, mutect2, varscan2
- SIK2 | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV59251222; called by muse, mutect2, varscan2
- SLC6A3 | c.1550G>C p.S517T | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV54362951; called by muse, varscan2
- TOP1MT | c.1213A>C p.T405P | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100239483; called by muse, mutect2, varscan2
- TPD52L2 | c.487A>C p.T163P | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV53862056; called by muse, mutect2, varscan2
- TRHDE | c.1709C>T p.T570I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV53838707; called by muse, mutect2, varscan2
- TRIM52 | c.682T>G p.F228V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59844090; called by muse, mutect2, varscan2
- TRIM67 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV64158518; called by muse, mutect2, varscan2
- TSPYL2 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV100966316; called by muse, mutect2
- USH2A | c.13531G>T p.A4511S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1330021955, COSV56349484; called by muse, mutect2, varscan2
- VPS26B | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs776450098, COSV55544564; called by muse, mutect2, varscan2
- YLPM1 | c.1627C>A p.P543T | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV53108990; called by muse, mutect2, varscan2
- ZFAT | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV64736577; called by muse, mutect2, varscan2
- ZFHX3 | c.5815G>C p.D1939H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV51713635; called by muse, mutect2, varscan2
- ZNF208 | c.83T>G p.L28* | Nonsense Mutation (SNP) | VAF 84/406 reads (21%) | catalogued as COSV68103041; called by muse, mutect2, varscan2
- ZNF263 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs750738145, COSV54595918, COSV99526759; called by muse, mutect2, varscan2
- ZNF568 | c.170T>A p.L57H | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV61740939; called by muse, mutect2, varscan2
- AP2M1 | c.424-6_429+8del p.X142_splice | Splice Site (DEL) | VAF 45/183 reads (25%) | called by mutect2, pindel, varscan2
- DCC | c.-16_18del | Translation Start Site (DEL) | VAF 38/260 reads (15%) | called by mutect2, pindel
- HNRNPD | c.720_723delinsTT p.M240Ifs*2 | Frame Shift Del (DEL) | VAF 83/156 reads (53%) | called by pindel, varscan2*
- MORC4 | c.2661-15_2664del p.X887_splice | Splice Site (DEL) | VAF 29/54 reads (54%) | called by mutect2, pindel, varscan2
- PRDM14 | c.507_514del p.P171Tfs*63 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | called by mutect2, pindel, varscan2
- RGS22 | c.615del p.D206Ifs*5 | Frame Shift Del (DEL) | VAF 39/228 reads (17%) | called by mutect2, pindel, varscan2
- ADAMTSL3 | c.390C>T p.F130= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs1434397679, COSV54442157; called by muse, mutect2, varscan2
- AMPH | c.810C>A p.L270= | Silent (SNP) | VAF 34/224 reads (15%) | catalogued as COSV57738242; called by muse, mutect2, varscan2
- CDIPT | c.297T>C p.S99= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV54888687; called by muse, mutect2, varscan2
- COL11A2 | c.723T>C p.P241= | Silent (SNP) | VAF 26/486 reads (5%) | catalogued as COSV100554178; called by muse, mutect2
- FBXO15 | c.1473C>G p.V491= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV54043953; called by muse, mutect2, varscan2
- GLIS3 | c.1842T>G p.P614= | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as COSV60926787; called by muse, mutect2, varscan2
- GRID1 | c.216A>T p.P72= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV60021407; called by muse, mutect2, varscan2
- GRIK1 | c.2733A>G p.K911= | Silent (SNP) | VAF 6/105 reads (6%) | catalogued as COSV100517140; called by muse, mutect2
- LNX1 | c.570C>T p.D190= (on ENST00000263925 / NM_001126328.3; = p.D94= on NM_032622.2) | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1013200223, COSV55783719; called by mutect2, varscan2
- LRP1B | c.4572G>A p.Q1524= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV101257882; called by muse, mutect2
- MYO18B | c.750C>T p.T250= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV100124063; called by muse, mutect2, varscan2
- PHF20 | c.2886G>A p.K962= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV64975320; called by muse, mutect2, varscan2
- PMFBP1 | c.1371G>A p.E457= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as rs1281972343, COSV52822290; called by muse, mutect2, varscan2
- QTRT2 | c.219C>G p.V73= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as COSV55559346; called by muse, mutect2, varscan2
- RAD54B | c.1872A>G p.L624= | Silent (SNP) | VAF 50/328 reads (15%) | catalogued as COSV60250525; called by muse, mutect2, varscan2
- SLC35F6 | c.423G>A p.V141= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as rs1043730767, COSV60426217; called by muse, mutect2, varscan2
- SLC47A1 | c.1383T>C p.N461= | Silent (SNP) | VAF 9/220 reads (4%) | catalogued as COSV99565413; called by muse, mutect2
- SOAT1 | c.453C>T p.L151= | Silent (SNP) | VAF 55/244 reads (23%) | catalogued as rs773748009, COSV62653477; called by muse, mutect2, varscan2
- TPSB2 | c.150C>G p.V50= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as COSV52353466; called by muse, mutect2, varscan2
- ZBTB11 | c.2823G>A p.V941= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1559980856, COSV57244566; called by muse, mutect2, varscan2
- ZNF219 | c.921C>T p.C307= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV53879173; called by muse, mutect2, varscan2
- EWSR1 | c.226+402A>G | Intron (SNP) | VAF 83/289 reads (29%) | catalogued as COSV58422607; called by muse, mutect2, varscan2
- GP6 | c.*31G>C | 3'UTR (SNP) | VAF 12/48 reads (25%) | catalogued as COSV59976891; called by muse, mutect2, varscan2
